Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3842, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3842-01A (Primary Tumor).

Diagnosis:

This is an adenocarcinoma of the colon, poorly differentiated, with a partial mucinous component, corresponding to G3, with infiltration of the muscularis and the vessels, corresponding to L1, V1, with free resection margins in the area of the mucosa and in the deep resection margin area, as well as lymph nodes in two sections with metastases of the carcinoma described corresponding to pN1.

Tumor classification:

ICDO-DA M-8140/3,

G3,

pT2, L1, V1, pN1 (2 of 12), locally R0, M classification in the context of an oncology conference.

Source: NCI Genomic Data Commons file 11bc525b-2ed2-4679-9aab-dbf8e85a65d8 (TCGA-AA-3842.890ECC56-472A-4B9B-8513-14C3D7FBD0D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).